Somatic mutation profile of tumor specimen TCGA-21-1082-01A (aliquot TCGA-21-1082-01A-01W-0782-08) from TCGA case TCGA-21-1082, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-21-1082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe374163-df72-420a-ac98-b4687469d16a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1082-10B (Blood Derived Normal), aliquot TCGA-21-1082-10B-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/964e380e-8f32-4c00-9e59-34bb980a5ffb

The open-access MAF lists 453 somatic variants for this specimen: 337 protein-altering or splice-affecting, 104 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 281, Silent 104, Nonsense Mutation 30, Frame Shift Del 14, RNA 7, Splice Site 5, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, Intron 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as rs387907144, CM122500, COSV51650129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 178/253 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100947537, COSV64420124; called by muse, mutect2, varscan2
- ADGRF4 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV99348969; called by muse, mutect2, varscan2
- ADGRL3 | c.1558G>T p.G520* (on ENST00000506720 / NM_001322402.2; = p.G452* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 403/878 reads (46%) | catalogued as COSV101547243; called by muse, mutect2, varscan2
- AL121899.2 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 206/360 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772095348, COSV67351818; called by muse, mutect2, varscan2
- ALDH5A1 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV62374927; called by muse, mutect2, varscan2
- ANKRD35 | c.1573C>G p.P525A | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62910521; called by muse, mutect2, varscan2
- ANKS1A | c.1482G>T p.Q494H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.556); catalogued as COSV64460944; called by muse, mutect2, varscan2
- APOB | c.11966G>A p.R3989H | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs148197354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99325602; called by muse, mutect2
- ATP13A2 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs761512701; called by mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 114/795 reads (14%) | catalogued as rs745882580; called by mutect2, varscan2
- BCHE | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs545173403; called by muse, mutect2, varscan2
- C10orf71 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 63/107 reads (59%) | catalogued as COSV100110366; called by muse, mutect2, varscan2
- C11orf80 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV100690963; called by muse, mutect2
- CACNA1B | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99055377; called by muse, mutect2, varscan2
- CACNA1B | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.927); catalogued as COSV53121174; called by muse, mutect2, varscan2
- CACNA1E | c.6512C>A p.S2171Y (on ENST00000367573 / NM_001205293.3; = p.S2128Y on NM_000721.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62384483; called by muse, mutect2, varscan2
- CASR | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 44/1417 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518616, CD165757; ClinVar: uncertain significance; called by muse, mutect2
- CCT8L2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV63463030; called by muse, mutect2, varscan2
- CD1B | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 613/1945 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs775272128; called by muse, mutect2, varscan2
- CD300C | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100423284; called by muse, mutect2, varscan2
- CEP68 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs773369946; called by muse, mutect2, varscan2
- CIB3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs761552234; called by muse, mutect2, varscan2
- CLSTN2 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 39/434 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs762229815; called by muse, mutect2
- COBL | c.3644A>C p.Q1215P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1345534130, COSV99473253; called by muse, varscan2
- CP | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 28/1050 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52830172; called by muse, mutect2
- CSMD1 | c.2810G>T p.G937V (on ENST00000520002; = p.G936V on NM_033225.6) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152348, COSV59358374; called by muse, mutect2, varscan2
- CYP2C18 | c.332-1G>C p.X111_splice | Splice Site (SNP) | VAF 16/229 reads (7%) | catalogued as COSV99608703; called by muse, mutect2
- CYP4F22 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs775752466; called by muse, mutect2, varscan2
- CYP4F8 | c.506A>T p.K169M | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs922556104, COSV100358166; called by muse, mutect2, varscan2
- CYRIA | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62866987; called by muse, mutect2, varscan2
- DGCR2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs776627102, COSV54216846, COSV99075874; called by muse, mutect2, varscan2
- DMBT1 | c.6231C>G p.I2077M (on ENST00000338354 / NM_001377530.1; = p.I1320M on NM_004406.3) | Missense Mutation (SNP) | VAF 194/414 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353937; called by muse, mutect2, varscan2
- DNAH5 | c.5939G>A p.G1980E | Missense Mutation (SNP) | VAF 114/562 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220504338; called by muse, mutect2, varscan2
- EIF2A | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs369784443; called by muse, mutect2, varscan2
- EPHA3 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 105/463 reads (23%) | catalogued as COSV60707285, COSV60725198; called by muse, mutect2, varscan2
- FAM47A | c.674del p.P225Rfs*41 | Frame Shift Del (DEL) | VAF 29/48 reads (60%) | catalogued as COSV60498580, COSV60499294; called by mutect2, pindel, varscan2
- FAM47A | c.99C>G p.C33W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60498649; called by muse, mutect2, varscan2
- FAT1 | c.9460G>A p.A3154T | Missense Mutation (SNP) | VAF 342/492 reads (70%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs759492838, COSV101499530; called by muse, varscan2
- FLG2 | c.6677C>T p.T2226I | Missense Mutation (SNP) | VAF 55/2078 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs916980875; called by muse, mutect2
- FLG2 | c.5326G>A p.D1776N | Missense Mutation (SNP) | VAF 54/927 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555660257, COSV66168591; called by muse, mutect2
- FNDC1 | c.3856C>A p.P1286T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1295580563; called by muse, mutect2, varscan2
- FUT10 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 254/740 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs140632284; called by muse, varscan2
- FUT10 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1563308068; called by muse, mutect2, varscan2
- GORASP2 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV99304628; called by muse, mutect2
- GPKOW | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs868990989; called by muse, mutect2
- GRID2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56241063, COSV99943257; called by muse, mutect2
- GRPR | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 219/337 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV66669905; called by muse, mutect2, varscan2
- GSDMB | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 253/419 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as rs1411495460; called by muse, mutect2, varscan2
- HECTD1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.19); catalogued as COSV101237428; called by muse, mutect2
- HSD3B2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs751984843, COSV65592990; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs761621429; called by mutect2, varscan2
- IGHMBP2 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as CM141742; called by muse, mutect2, varscan2
- IGKV2-24 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 138/377 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1352090689; called by muse, mutect2, varscan2
- KEL | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 104/191 reads (54%) | catalogued as rs61729052, CM022220; called by muse, mutect2, varscan2
- KRTAP21-2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100441147, COSV61684150; called by muse, mutect2, varscan2
- LCE1D | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 30/122 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV58271381; called by muse, mutect2, varscan2
- LENG1 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs750793889; called by muse, varscan2
- LHCGR | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 161/371 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs377265035; called by muse, mutect2, varscan2
- LRP1B | c.6503G>A p.C2168Y | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67195334; called by muse, mutect2, varscan2
- LRRC36 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52081718; called by muse, mutect2
- MAGEL2 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100046193, COSV99041371; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.495); catalogued as rs751996288, COSV51718877, COSV51722167; called by muse, mutect2, varscan2
- MMP28 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs757698905; called by muse, mutect2
- MX2 | c.250-2A>T p.X84_splice | Splice Site (SNP) | VAF 38/119 reads (32%) | catalogued as COSV100416031; called by muse, mutect2, varscan2
- NFAT5 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63026102; called by muse, mutect2, varscan2
- NFIC | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866417103, COSV59412951; called by muse, mutect2, varscan2
- NPC1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 103/563 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs751947520; called by muse, mutect2, varscan2
- NPC1L1 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1214741307; called by muse, mutect2, varscan2
- NR3C2 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.835); catalogued as rs776290874, COSV60996932; called by muse, mutect2, varscan2
- NRXN3 | c.1659G>T p.E553D (on ENST00000557594 / NM_001272020.2; = p.E977D on NM_004796.6) | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs762264384, COSV55344705; called by muse, mutect2, varscan2
- NUP210L | c.4303G>T p.D1435Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99668521; called by muse, mutect2, varscan2
- NUP210L | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55150859; called by muse, mutect2, varscan2
- NWD1 | c.3818del p.G1273Afs*12 | Frame Shift Del (DEL) | VAF 161/279 reads (58%) | catalogued as COSV60352425; called by mutect2, pindel*, varscan2
- OCA2 | c.1662G>T p.W554C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62339015; called by muse, mutect2, varscan2
- OCLN | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778368708, COSV62284981; called by muse, mutect2, varscan2
- OR1S2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100224273; called by muse, mutect2, varscan2
- OR4L1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV59849785; called by muse, mutect2, varscan2
- OR8B8 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 236/540 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.721); catalogued as rs767201422; called by muse, mutect2, varscan2
- PADI6 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100639965, COSV61884539; called by muse, mutect2, varscan2
- PAH | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM961077; called by muse, mutect2, varscan2
- PCDHA1 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as rs781822757, COSV65373768; called by muse, mutect2, varscan2
- PCDHA4 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.063); catalogued as COSV63546224; called by muse, mutect2, varscan2
- PCDHB11 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100697081; called by muse, mutect2, varscan2
- PHYH | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99036312; called by muse, mutect2, varscan2
- PLEKHO2 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60262018; called by muse, mutect2, varscan2
- POM121L12 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.422); catalogued as COSV68694200; called by muse, mutect2, varscan2
- POP1 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 520/1262 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs149744031; called by muse, varscan2
- PPP4R1 | c.1234del p.S412Qfs*37 (on ENST00000400556 / NM_001042388.3; = p.S395Qfs*37 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as COSV53280543; called by mutect2, pindel*, varscan2*
- PRAME | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769323726; called by muse, mutect2, varscan2
- PTPRC | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 125/317 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100722422; called by muse, mutect2, varscan2
- PTPRD | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 18/143 reads (13%) | catalogued as COSV61957239; called by muse, mutect2, varscan2
- PUM3 | c.1023dup p.K342Qfs*8 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | catalogued as rs749329036; called by pindel, varscan2
- RBM12 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 31/928 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100467748; called by muse, mutect2
- RFX6 | c.2053A>G p.I685V | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs369719975; called by muse, mutect2, varscan2
- RIMS1 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53474518; called by muse, mutect2, varscan2
- RIPK3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as rs1465184165, COSV53476555; called by muse, mutect2
- RNF32 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 132/260 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV58733452; called by muse, mutect2, varscan2
- RTBDN | c.475G>C p.G159R (on ENST00000393233 / NM_001270444.1; = p.G191R on NM_031429.2) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs537117488, COSV100530726; called by muse, mutect2, varscan2
- RYR2 | c.7993G>T p.A2665S | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV100771999, COSV63672383, COSV63688685; called by muse, mutect2, varscan2
- RYR3 | c.2508T>A p.D836E | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV66807412; called by muse, mutect2, varscan2
- S100A7 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs777094796; called by muse, mutect2, varscan2
- SFRP4 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs572680887; called by muse, mutect2, varscan2
- SGK2 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 234/439 reads (53%) | catalogued as COSV58315018; called by muse, mutect2, varscan2
- SHANK1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV53256140; called by muse, mutect2, varscan2
- SIGLEC5 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as rs1397495214; called by muse, mutect2, varscan2
- SLC13A1 | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1251828107, COSV52018527; called by muse, mutect2, varscan2
- SLC9A2 | c.2068+1G>T p.X690_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99296477; called by muse, mutect2, varscan2
- SLCO1B1 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778697943, COSV57012833; called by muse, mutect2, varscan2
- SLCO2A1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774038272, CM1312618, COSV100189501; called by muse, mutect2, varscan2
- SLITRK2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs868958000; called by muse, varscan2
- SLITRK6 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs369642690, COSV68390459; called by muse, varscan2
- SNTG1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.188); catalogued as COSV52475315; called by muse, mutect2, varscan2
- SOGA1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968990795; called by muse, mutect2, varscan2
- SPRY3 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 239/441 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57143273; called by muse, mutect2, varscan2
- TAF11 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63543035; called by mutect2, varscan2
- TBCC | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as rs752952851; called by mutect2, varscan2
- TCF25 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as COSV54529926; called by muse, mutect2, varscan2
- TGM6 | c.621C>G p.D207E | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs148696208; called by muse, mutect2, varscan2
- TGS1 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52703627, COSV99485395; called by muse, mutect2, varscan2
- TMEM131L | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV99548373; called by muse, mutect2, varscan2
- TRIML2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV58714688; called by muse, varscan2
- UBE4A | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 34/770 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV99348367; called by muse, mutect2
- UGT1A4 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.305); catalogued as COSV100530486; called by muse, mutect2
- WASHC2C | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs1554876649, COSV100314098; called by muse, mutect2, varscan2
- ZBBX | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs760372262, COSV56794402; called by muse, mutect2, varscan2
- ZC3H12C | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 150/567 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV99584558; called by muse, mutect2, varscan2
- ZFHX3 | c.9949C>T p.P3317S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.341); catalogued as rs575725460; called by muse, mutect2, varscan2
- ZNF107 | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs575000457; called by muse, mutect2, varscan2
- ZNF20 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503029; called by muse, mutect2, varscan2
- ZNF205 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs775487028, COSV54622134; called by muse, mutect2, varscan2
- ZNF33A | c.2303_2304del p.R768Kfs*10 (on ENST00000458705 / NM_006974.3; = p.R769Kfs*10 on NM_006954.2) | Frame Shift Del (DEL) | VAF 64/249 reads (26%) | catalogued as COSV56726361; called by pindel, varscan2
- ZNF516 | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101487269; called by muse, mutect2, varscan2
- ZNF696 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530763271, COSV57524891; called by muse, mutect2, varscan2
- ZNF709 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs752544330; called by muse, mutect2, varscan2
- AASS | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ABCC12 | c.249T>A p.Y83* | Nonsense Mutation (SNP) | VAF 150/505 reads (30%) | called by muse, mutect2, varscan2
- ACVR1 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 112/185 reads (61%) | called by muse, mutect2, varscan2
- ADAD1 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ADAM18 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADAMTS2 | c.690G>T p.G230= | Splice Region (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2
- ADAMTS20 | c.3633G>T p.W1211C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTS20 | c.3632G>T p.W1211L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ADIPOR1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.16346C>T p.A5449V | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2
- ALS2CL | c.2144A>T p.E715V | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ANK1 | c.5305G>C p.E1769Q | Missense Mutation (SNP) | VAF 136/367 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANK2 | c.5113A>G p.R1705G | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ANKRD35 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 137/369 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APLNR | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 155/535 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF3 | c.4006G>C p.E1336Q | Missense Mutation (SNP) | VAF 20/433 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP18 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 87/337 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP29 | c.1088del p.N363Ifs*6 | Frame Shift Del (DEL) | VAF 35/190 reads (18%) | called by pindel, varscan2
- ARHGAP29 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- ARHGAP33 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ARHGAP36 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 108/143 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP36 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 229/379 reads (60%) | called by muse, mutect2, varscan2
- ASCL1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ATP13A3 | c.39A>C p.Q13H | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- ATP2C2 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 178/664 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AWAT1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 46/64 reads (72%) | called by muse, mutect2, varscan2
- BCL9L | c.2981G>T p.R994M | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- BICD1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRDT | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2
- BRPF3 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- C11orf16 | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- C3orf38 | c.923G>A p.C308Y | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.483); called by muse, mutect2
- C8orf34 | c.335del p.M112Rfs*4 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- CARS2 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP14 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 204/987 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLL1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CCNB3 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 90/129 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD93 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDYL | c.1630A>T p.N544Y (on ENST00000328908 / NM_001368125.1; = p.N490Y on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP250 | c.7156G>T p.G2386C | Missense Mutation (SNP) | VAF 152/310 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CEP290 | c.3677C>G p.S1226C | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CFAP299 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 129/298 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CLMP | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 107/204 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CLN3 | c.1020G>T p.W340C (on ENST00000360019 / NM_001286104.2; = p.W364C on NM_000086.2) | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CMYA5 | c.6484G>T p.A2162S | Missense Mutation (SNP) | VAF 146/263 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- COL6A3 | c.6575G>T p.G2192V | Missense Mutation (SNP) | VAF 355/1137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.7950C>A p.N2650K (on ENST00000520002; = p.N2649K on NM_033225.6) | Missense Mutation (SNP) | VAF 353/913 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CTH | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNNA2 | c.2606C>A p.A869D (on ENST00000402739 / NM_001282597.3; = p.A821D on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4V2 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYSLTR2 | c.267C>A p.S89R | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- DAND5 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- DDX25 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- DNAJC19 | c.244C>G p.H82D | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOCK8 | c.4409A>G p.N1470S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- DRG1 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 407/1319 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DSCAM | c.5176C>A p.P1726T | Missense Mutation (SNP) | VAF 113/386 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DSG4 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DYRK4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EBF2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- EGFLAM | c.2947G>A p.G983R (on ENST00000354891 / NM_001205301.2; = p.G975R on NM_152403.4) | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM71A | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- FAM83G | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLG2 | c.5971C>T p.H1991Y | Missense Mutation (SNP) | VAF 46/1440 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- GLP2R | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 150/246 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPATCH2 | c.457G>T p.V153F | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GTF3C5 | c.536del p.P179Rfs*26 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | called by mutect2, varscan2
- H4C3 | c.30_40del p.L11Wfs*3 | Frame Shift Del (DEL) | VAF 38/184 reads (21%) | called by mutect2, pindel, varscan2
- HAUS1 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HINFP | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HPSE2 | c.84C>A p.Y28* | Nonsense Mutation (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2, varscan2
- IGKV1D-8 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- IGLV10-54 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- IKBIP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- INMT | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 147/485 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IPO4 | c.2470C>G p.Q824E | Missense Mutation (SNP) | VAF 18/626 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- ITGB1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, varscan2
- JPH3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KANK4 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNC2 | c.545A>C p.D182A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNH1 | c.1501A>G p.I501V (on ENST00000271751 / NM_172362.3; = p.I474V on NM_002238.4) | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KHNYN | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHSRP | c.1009del p.V337Sfs*8 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- KMT2A | c.3570-1G>A p.X1190_splice | Splice Site (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- KNL1 | c.933G>T p.Q311H (on ENST00000346991 / NM_170589.5; = p.Q285H on NM_144508.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LILRB5 | c.1313C>A p.P438H (on ENST00000449561 / NM_001081442.3; = p.P437H on NM_006840.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- LNP1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG3 | c.2683C>G p.H895D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- LRP1B | c.8327C>A p.P2776H | Missense Mutation (SNP) | VAF 220/350 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- LRP1B | c.2201G>T p.S734I | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2
- LRP1B | c.1696_1702del p.E566Ifs*12 | Frame Shift Del (DEL) | VAF 147/367 reads (40%) | called by mutect2, pindel, varscan2
- LRRK1 | c.6016C>G p.R2006G | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- LRRTM4 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSS | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, varscan2
- MACF1 | c.20971G>A p.A6991T (on ENST00000372915; = p.A5036T on NM_012090.5) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.1452A>G p.K484= | Splice Region (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- MARF1 | c.2611del p.A871Lfs*9 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- METTL21C | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MGAT4A | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MIXL1 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MLLT10 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- MRPL47 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPS35 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOM3 | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYOM3 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- MYOT | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.5638C>G p.Q1880E (on ENST00000397909 / NM_001024383.2; = p.Q1858E on NM_014903.6) | Missense Mutation (SNP) | VAF 83/400 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NCAPG | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NEK3 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- NOP53 | c.1407G>C p.E469D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOS2 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- NPAT | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPTXR | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP210L | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 69/320 reads (22%) | called by muse, mutect2, varscan2
- OR10Q1 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, varscan2
- OR2G3 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 269/599 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4K1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- OSGIN2 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PAN2 | c.3409A>G p.I1137V (on ENST00000425394 / NM_001127460.3; = p.I1133V on NM_014871.5) | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PANX3 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PAPPA2 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 235/918 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD9 | c.387A>T p.K129N (on ENST00000424898 / NM_001363519.1; = p.K69N on NM_173806.4) | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- PHF20 | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 124/585 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PIK3CB | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- PLCH1 | c.155G>T p.R52L (on ENST00000340059 / NM_001130960.2; = p.R64L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 430/852 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- PLOD2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 137/739 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- POLR2A | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POTEA | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- POTEH | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, varscan2
- PPIL6 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRKDC | c.5830G>T p.A1944S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKN | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRMT5 | c.453C>T p.F151= | Splice Region (SNP) | VAF 37/260 reads (14%) | called by muse, mutect2, varscan2
- PRSS12 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- PSME4 | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PTPRM | c.2218A>T p.T740S | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2
- R3HDM1 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RANBP2 | c.4381C>T p.Q1461* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- RERG | c.595A>G p.S199G | Missense Mutation (SNP) | VAF 131/420 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RET | c.2749T>C p.W917R | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIOX2 | c.1153G>A p.E385K (on ENST00000333396 / NM_001042533.2; = p.E384K on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- RTL3 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SACS | c.5163del p.A1723Hfs*2 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- SCLY | c.844G>T p.G282C (on ENST00000651534; = p.G274C on NM_016510.7) | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SDHA | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.113); called by muse, mutect2
- SF3A1 | c.827G>A p.W276* | Nonsense Mutation (SNP) | VAF 175/543 reads (32%) | called by muse, mutect2, varscan2
- SF3B2 | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SIGLEC1 | c.3560A>T p.Q1187L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); called by muse, varscan2
- SIPA1L2 | c.2734G>C p.V912L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- SLC28A1 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 81/722 reads (11%) | called by muse, mutect2, varscan2
- SLC5A5 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SLF1 | c.2502C>G p.I834M | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLIT2 | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 128/255 reads (50%) | called by muse, mutect2, varscan2
- SMG6 | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 433/670 reads (65%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SOHLH1 | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPEF2 | c.3478A>C p.N1160H | Missense Mutation (SNP) | VAF 73/589 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SPIB | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPIDR | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPRY2 | c.939del p.K313Nfs*42 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- SQOR | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- STAB1 | c.6578C>G p.S2193* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- STYXL2 | c.1774T>A p.W592R | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- STYXL2 | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SUCO | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUGP1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 44/175 reads (25%) | called by muse, mutect2, varscan2
- TAAR1 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- TAAR5 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R41 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAS2R43 | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.399); called by muse, varscan2
- TBCC | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- TBL1Y | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TEAD3 | c.1285G>C p.V429L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.569); called by muse, mutect2
- TMEM41A | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMX4 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 241/466 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, varscan2
- TNC | c.3404A>G p.K1135R | Missense Mutation (SNP) | VAF 72/632 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.098); called by muse, mutect2
- TNFRSF11B | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 309/750 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNIK | c.2962G>C p.D988H | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TNR | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TOX2 | c.657G>T p.E219D (on ENST00000358131 / NM_001098798.2; = p.E168D on NM_032883.3) | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TOX2 | c.658G>T p.E220* (on ENST00000358131 / NM_001098798.2; = p.E169* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 86/181 reads (48%) | called by muse, mutect2, varscan2
- TP53 | c.575_580del p.Q192_H193del | In Frame Del (DEL) | VAF 81/183 reads (44%) | called by mutect2, pindel, varscan2
- TPPP2 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 178/612 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- TRABD2A | c.1156G>T p.V386L (on ENST00000409520 / NM_001277053.2; = p.V337L on NM_001080824.3) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBN1 | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- UBR2 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- USP33 | c.806A>C p.Q269P | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13C | c.10775C>G p.S3592C (on ENST00000644861 / NM_020821.3; = p.S3549C on NM_017684.5) | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WBP1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR35 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- XAB2 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZAP70 | c.1104C>G p.I368M | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZBBX | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 101/681 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ZFHX3 | c.10148T>C p.L3383P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by mutect2, varscan2
- ZFHX3 | c.9608A>G p.Q3203R | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); called by muse, varscan2
- ZNF200 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- ZNF786 | c.2300del p.K767Rfs*10 | Frame Shift Del (DEL) | VAF 115/299 reads (38%) | called by mutect2, pindel, varscan2
- ZNF80 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZPR1 | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 73/218 reads (33%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 169/605 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACTRT2 | c.186C>T p.A62= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs756159916, COSV101007638; called by muse, mutect2, varscan2
- AGO1 | c.2208C>A p.T736= | Silent (SNP) | VAF 160/2712 reads (6%) | catalogued as COSV64596470; called by muse, mutect2
- ARHGAP35 | c.918G>A p.Q306= | Silent (SNP) | VAF 8/77 reads (10%) | called by muse, varscan2
- ARMC1 | c.75A>G p.A25= | Silent (SNP) | VAF 144/477 reads (30%) | called by muse, mutect2, varscan2
- ARSG | c.621C>G p.L207= | Silent (SNP) | VAF 60/154 reads (39%) | catalogued as COSV101477873, COSV71593698; called by muse, mutect2, varscan2
- ASB9 | c.39C>G p.P13= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV66852309; called by muse, mutect2, varscan2
- AWAT1 | c.855C>A p.P285= | Silent (SNP) | VAF 46/65 reads (71%) | called by muse, mutect2, varscan2
- BTBD8 | c.621T>C p.D207= | Silent (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- C9orf43 | c.609A>G p.L203= | Silent (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- CAB39L | c.807C>A p.I269= | Silent (SNP) | VAF 168/378 reads (44%) | catalogued as COSV61715566; called by mutect2, varscan2
- CAV1 | c.453C>T p.Y151= | Silent (SNP) | VAF 63/162 reads (39%) | catalogued as rs750447403; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC60 | c.48G>T p.S16= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- CD320 | c.771G>A p.E257= | Silent (SNP) | VAF 128/314 reads (41%) | called by muse, mutect2, varscan2
- CDH4 | c.1155G>A p.V385= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs756029114; called by muse, mutect2, varscan2
- CFHR4 | c.45T>C p.C15= | Silent (SNP) | VAF 99/281 reads (35%) | called by muse, mutect2, varscan2
- CHST3 | c.153G>A p.K51= | Silent (SNP) | VAF 33/50 reads (66%) | called by muse, mutect2, varscan2
- COL4A4 | c.3765T>A p.P1255= | Silent (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- CRYZL1 | c.855G>C p.L285= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- CSMD1 | c.6507C>A p.I2169= (on ENST00000520002; = p.I2168= on NM_033225.6) | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV59357293; called by muse, mutect2, varscan2
- CYP2E1 | c.1011A>G p.R337= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- DCLK1 | c.99G>A p.P33= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as rs754667282; called by muse, mutect2, varscan2
- DCT | c.456A>G p.V152= | Silent (SNP) | VAF 349/945 reads (37%) | called by muse, mutect2, varscan2
- DDX27 | c.1017G>T p.A339= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- DDX54 | c.1320C>T p.S440= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1566096429; called by muse, mutect2
- DMRT3 | c.1053C>A p.P351= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV51908447; called by muse, mutect2, varscan2
- DNAH5 | c.10899C>T p.F3633= | Silent (SNP) | VAF 69/663 reads (10%) | called by muse, mutect2, varscan2
- DNAJC28 | c.798T>A p.T266= | Silent (SNP) | VAF 308/557 reads (55%) | called by muse, mutect2, varscan2
- DUOX1 | c.2199G>A p.L733= | Silent (SNP) | VAF 54/181 reads (30%) | called by muse, mutect2, varscan2
- ENPP2 | c.90A>T p.A30= | Silent (SNP) | VAF 16/500 reads (3%) | called by muse, mutect2
- ESPL1 | c.2151G>A p.L717= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- FAM167A | c.249C>A p.L83= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99461409; called by muse, mutect2, varscan2
- FOXM1 | c.261C>T p.I87= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs11548398, COSV100700929; called by muse, mutect2, varscan2
- FSIP1 | c.1674C>G p.L558= | Silent (SNP) | VAF 92/325 reads (28%) | called by muse, mutect2, varscan2
- G6PC | c.585C>T p.F195= | Silent (SNP) | VAF 50/283 reads (18%) | catalogued as COSV53832384; called by mutect2, varscan2
- GPR19 | c.594G>A p.V198= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs1406333486; called by muse, mutect2
- HLTF | c.366C>T p.I122= | Silent (SNP) | VAF 42/396 reads (11%) | catalogued as rs753530650, COSV100026945; called by muse, mutect2
- HMGN3 | c.90G>A p.L30= | Silent (SNP) | VAF 268/1018 reads (26%) | called by muse, mutect2, varscan2
- HTR3C | c.1167A>C p.A389= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- IFT52 | c.1056G>A p.E352= | Silent (SNP) | VAF 124/155 reads (80%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.315T>C p.F105= | Silent (SNP) | VAF 13/74 reads (18%) | called by mutect2, varscan2
- IRX2 | c.747G>T p.L249= | Silent (SNP) | VAF 38/65 reads (58%) | called by muse, mutect2, varscan2
- ITGA10 | c.720A>C p.G240= | Silent (SNP) | VAF 78/327 reads (24%) | called by muse, mutect2, varscan2
- JPH3 | c.906G>A p.V302= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs548027626; called by muse, mutect2, varscan2
- KRT82 | c.915C>A p.A305= | Silent (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- LRRC27 | c.720G>T p.L240= | Silent (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- MAD2L1BP | c.522C>G p.P174= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- MAP2K3 | c.760C>T p.L254= (on ENST00000342679 / NM_145109.3; = p.L225= on NM_002756.4) | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs763941994, COSV100384148; called by muse, mutect2, varscan2
- MAPRE2 | c.105C>G p.R35= | Silent (SNP) | VAF 131/270 reads (49%) | called by muse, mutect2, varscan2
- MCM3AP | c.2907G>A p.G969= | Silent (SNP) | VAF 36/351 reads (10%) | called by muse, mutect2, varscan2
- MIGA1 | c.972G>T p.T324= | Silent (SNP) | VAF 81/273 reads (30%) | catalogued as rs778601298; called by muse, mutect2, varscan2
- MKI67 | c.1161T>C p.D387= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, varscan2
- MRTFA | c.870C>T p.P290= | Silent (SNP) | VAF 11/269 reads (4%) | called by muse, mutect2
- MUC16 | c.28947T>A p.S9649= | Silent (SNP) | VAF 201/381 reads (53%) | called by muse, mutect2, varscan2
- MYCBP2 | c.7308G>A p.K2436= (on ENST00000357337; = p.K2474= on NM_015057.5) | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs1300829455, COSV62012495; called by muse, mutect2, varscan2
- MYH1 | c.2967G>A p.L989= | Silent (SNP) | VAF 164/283 reads (58%) | catalogued as COSV56845069, COSV99874705; called by muse, mutect2, varscan2
- NEK3 | c.150G>A p.E50= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2
- NEUROD6 | c.552C>T p.N184= | Silent (SNP) | VAF 152/495 reads (31%) | catalogued as rs967547086, COSV51771421; called by muse, mutect2, varscan2
- NOL11 | c.291G>A p.L97= | Silent (SNP) | VAF 102/153 reads (67%) | called by muse, mutect2, varscan2
- NOL4 | c.1644T>C p.N548= | Silent (SNP) | VAF 197/654 reads (30%) | called by muse, mutect2, varscan2
- NOP2 | c.1488G>C p.L496= (on ENST00000322166 / NM_001258308.2; = p.L492= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 165/411 reads (40%) | catalogued as COSV59110153, COSV59111892; called by muse, mutect2, varscan2
- NUMA1 | c.678G>A p.E226= | Silent (SNP) | VAF 68/411 reads (17%) | called by muse, mutect2, varscan2
- OBSL1 | c.4704G>A p.V1568= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV54707598; called by muse, mutect2, varscan2
- OLFM2 | c.721C>A p.R241= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- OR6C75 | c.201G>T p.L67= | Silent (SNP) | VAF 153/422 reads (36%) | called by muse, varscan2
- PABPC1L | c.562C>T p.L188= | Silent (SNP) | VAF 26/372 reads (7%) | catalogued as COSV99408216; called by muse, mutect2
- PBX4 | c.642G>T p.R214= | Silent (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- PCLO | c.7731A>G p.T2577= | Silent (SNP) | VAF 188/326 reads (58%) | called by muse, mutect2, varscan2
- PDCD1 | c.810C>A p.G270= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- PDGFB | c.495T>C p.F165= | Silent (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- PECR | c.522A>T p.A174= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs768006106; called by muse, mutect2, varscan2
- PLXNA1 | c.4191G>T p.L1397= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- POU6F2 | c.384G>C p.A128= | Silent (SNP) | VAF 80/293 reads (27%) | catalogued as rs1283569251, COSV68874521; called by muse, mutect2, varscan2
- PREX1 | c.2640C>T p.F880= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs373448744; called by muse, mutect2, varscan2
- RCC1 | c.753C>T p.F251= | Silent (SNP) | VAF 81/415 reads (20%) | catalogued as rs775522858; called by muse, mutect2, varscan2
- RFX6 | c.1153C>A p.R385= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as CM166833, COSV60587707; called by muse, mutect2, varscan2
- RHOBTB2 | c.2148C>G p.S716= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1460494102; called by muse, mutect2
- RSU1 | c.567G>T p.G189= | Silent (SNP) | VAF 398/605 reads (66%) | called by muse, mutect2, varscan2
- SAMD4A | c.2028G>A p.L676= | Silent (SNP) | VAF 175/435 reads (40%) | called by muse, mutect2, varscan2
- SBDS | c.717G>C p.L239= | Silent (SNP) | VAF 65/183 reads (36%) | catalogued as COSV55887474; called by muse, mutect2, varscan2
- SERPINB5 | c.384G>A p.T128= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs757336116, COSV66975161; called by muse, mutect2, varscan2
- SH3GLB2 | c.345G>A p.L115= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- SIGLEC1 | c.1782G>T p.V594= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
- SIPA1L3 | c.504C>T p.H168= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1680G>T p.R560= | Silent (SNP) | VAF 53/184 reads (29%) | called by muse, mutect2, varscan2
- SLC2A2 | c.1032A>T p.G344= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- SLC35B2 | c.675G>A p.L225= | Silent (SNP) | VAF 106/373 reads (28%) | called by muse, mutect2, varscan2
- SMAP1 | c.981A>T p.T327= (on ENST00000370455 / NM_001044305.3; = p.T300= on NM_021940.5) | Silent (SNP) | VAF 83/234 reads (35%) | called by muse, mutect2, varscan2
- SON | c.147A>C p.A49= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- SPA17 | c.123C>G p.A41= | Silent (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- SYT6 | c.333C>T p.F111= (on ENST00000610222 / NM_001366225.1; = p.F26= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/390 reads (31%) | called by muse, mutect2, varscan2
- TMEM202 | c.459G>T p.L153= | Silent (SNP) | VAF 132/459 reads (29%) | called by muse, mutect2, varscan2
- TMEM63C | c.1407G>A p.L469= | Silent (SNP) | VAF 87/241 reads (36%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.753G>A p.R251= | Silent (SNP) | VAF 33/60 reads (55%) | called by mutect2, varscan2
- TRAV16 | c.225C>T p.I75= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- TRPM8 | c.3087C>T p.F1029= | Silent (SNP) | VAF 23/440 reads (5%) | called by muse, mutect2
- TTK | c.1530A>G p.A510= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as COSV100036428; called by muse, mutect2, varscan2
- TUBB6 | c.225C>T p.S75= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1267098226, COSV58354476; called by muse, mutect2, varscan2
- UBN1 | c.2964G>A p.L988= | Silent (SNP) | VAF 40/313 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.2670C>A p.T890= | Silent (SNP) | VAF 187/433 reads (43%) | catalogued as rs1164198981, COSV100238639; called by muse, mutect2, varscan2
- USHBP1 | c.1425C>A p.P475= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- VPS54 | c.1131A>G p.L377= | Silent (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- WDR49 | c.201C>T p.A67= (on ENST00000308378 / NM_001366158.1; = p.A408= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 123/702 reads (18%) | catalogued as rs370189335; called by muse, mutect2, varscan2
- ZNF566 | c.354C>T p.F118= | Silent (SNP) | VAF 38/494 reads (8%) | catalogued as COSV101091485; called by muse, mutect2
- ZNF668 | c.693G>A p.K231= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668245 G>C | 5'Flank (SNP) | VAF 120/503 reads (24%) | called by muse, varscan2
- AL133467.6 | chr14:95668319 G>T | 5'Flank (SNP) | VAF 52/222 reads (23%) | called by muse, varscan2
- CD300LD | chr17:74592656 G>A | 5'Flank (SNP) | VAF 68/232 reads (29%) | called by muse, mutect2, varscan2
- FAM74A3 | n.53G>A | RNA (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- FBXL21P | n.988A>T | RNA (SNP) | VAF 118/250 reads (47%) | catalogued as COSV99778374; called by muse, mutect2, varscan2
- IGKV1-13 | n.316T>C | RNA (SNP) | VAF 127/753 reads (17%) | called by muse, mutect2, varscan2
- MIR18A | n.2G>C | RNA (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.409C>G | RNA (SNP) | VAF 14/70 reads (20%) | called by muse, varscan2
- PCDHA9 | c.2394+11C>G | Intron (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112220221 G>A | 3'Flank (SNP) | VAF 60/130 reads (46%) | catalogued as rs1268662556, COSV100534377; called by muse, mutect2
- SNORD114-29 | n.13G>A | RNA (SNP) | VAF 22/470 reads (5%) | called by muse, mutect2
- XIST | n.8731G>T | RNA (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
